Somatic mutation profile of tumor specimen TCGA-AA-3966-01A (aliquot TCGA-AA-3966-01A-01D-1981-10) from TCGA case TCGA-AA-3966, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 89.1 years (32,537 days).
Specimen TCGA-AA-3966-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b62ecd6d-c88c-4e92-8aa6-5285cf9708da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3966-10A (Blood Derived Normal), aliquot TCGA-AA-3966-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79ccdd0e-070b-46f8-b55d-1e5465516a10

The open-access MAF lists 1,518 somatic variants for this specimen: 1,200 protein-altering or splice-affecting, 294 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 818, Silent 294, Frame Shift Del 251, Frame Shift Ins 55, Nonsense Mutation 41, Splice Site 19, Intron 16, In Frame Del 8, Splice Region 6, RNA 4, 3'UTR 3, 3'Flank 1.

Variants (750 of 1,518; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.126dup p.L43Afs*125 | Frame Shift Ins (INS) | VAF 34/109 reads (31%) | catalogued as rs180177171; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ANKRD11 | c.3309del p.D1104Mfs*214 | Frame Shift Del (DEL) | VAF 37/139 reads (27%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 164/526 reads (31%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- EGFR | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.152); catalogued as rs150036236, COSV51801471; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- EPG5 | c.6020_6021del p.C2007Yfs*2 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | catalogued as rs1064795230; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ESCO2 | c.760del p.T254Lfs*13 | Frame Shift Del (DEL) | VAF 44/130 reads (34%) | catalogued as rs80359852; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 59/271 reads (22%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 46/216 reads (21%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- NOTCH2 | c.3246dup p.A1083Sfs*17 | Frame Shift Ins (INS) | VAF 50/337 reads (15%) | catalogued as rs1553195973; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PNKP | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs267606957, CM101221, COSV55586666; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SEC63 | c.452+1G>A p.X151_splice | Splice Site (SNP) | VAF 34/212 reads (16%) | catalogued as rs869312977, COSV100938292; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 100/252 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 76/253 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 50/204 reads (25%) | catalogued as rs751284215; called by mutect2, pindel, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs771808127, COSV55113098; called by pindel, varscan2
- AASS | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 112/211 reads (53%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.961); catalogued as rs868487258, COSV62790109; called by muse, mutect2, varscan2
- ABCA12 | c.5399C>T p.T1800M (on ENST00000272895 / NM_173076.3; = p.T1482M on NM_015657.3) | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs541331115, COSV55955972; called by muse, mutect2, varscan2
- ABCA13 | c.10358T>G p.L3453W | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV71288234; called by muse, mutect2, varscan2
- ABCA4 | c.6386G>T p.S2129I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV64673711; called by muse, mutect2, varscan2
- ABCA8 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV52201741; called by muse, mutect2, varscan2
- ABCC11 | c.1967T>G p.L656R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62323219; called by muse, mutect2, varscan2
- ABCC11 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746920060, COSV62323226; called by muse, mutect2, varscan2
- ABLIM1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs202220476, COSV53301485, COSV99522116; called by muse, mutect2, varscan2
- ACAD10 | c.2704G>T p.G902C | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58157424, COSV58163505; called by muse, mutect2, varscan2
- ACOT11 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as rs762558370, COSV59346198; called by muse, mutect2
- ACTR1A | c.987+2T>C p.X329_splice | Splice Site (SNP) | VAF 32/126 reads (25%) | catalogued as COSV99487676; called by muse, mutect2, varscan2
- ACVR1C | c.914A>C p.H305P | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54646355; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 100/138 reads (72%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs765853980, COSV61702301; called by muse, mutect2, varscan2
- ADAD1 | c.959T>A p.I320N | Missense Mutation (SNP) | VAF 94/560 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV56643690; called by muse, mutect2, varscan2
- ADAMTS20 | c.434T>G p.V145G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV67130125; called by muse, mutect2, varscan2
- ADAMTS3 | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 105/248 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as rs557435473, COSV54388875; called by muse, mutect2, varscan2
- ADAMTS3 | c.2644C>A p.H882N | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as COSV54391894, COSV54406140; called by muse, mutect2, varscan2
- ADAMTSL1 | c.724A>G p.S242G | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.444); catalogued as rs752983559, COSV52816021; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 17/145 reads (12%) | catalogued as COSV65879385; called by mutect2, pindel, varscan2
- ADAT1 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs754878846, COSV57186673; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 30/42 reads (71%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRF1 | c.1979C>A p.A660D | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99346875; called by muse, mutect2, varscan2
- ADGRV1 | c.15415G>A p.E5139K | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs776241274, COSV67985546; called by muse, mutect2, varscan2
- AFAP1 | c.2035T>G p.S679A | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.626); catalogued as rs768168136, COSV61795712; called by mutect2, varscan2
- AGO1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774432228, COSV64595117; called by muse, mutect2, varscan2
- AGO1 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs1230155462; called by muse, mutect2, varscan2
- AGPAT3 | c.942G>T p.W314C | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52370470, COSV99377464; called by muse, mutect2, varscan2
- AHCTF1 | c.295C>T p.R99* (on ENST00000366508; = p.R73* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 51/363 reads (14%) | catalogued as COSV58250416; called by muse, mutect2, varscan2
- AHCY | c.722T>C p.I241T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV54153247; called by muse, mutect2, varscan2
- AHDC1 | c.3256T>G p.S1086A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.9); PolyPhen possibly damaging (0.525); catalogued as rs766744511, COSV55937122; called by muse, mutect2, varscan2
- AHNAK | c.5879T>C p.V1960A | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV57214181; called by muse, mutect2, varscan2
- AIFM1 | c.350-2A>G p.X117_splice | Splice Site (SNP) | VAF 109/193 reads (56%) | catalogued as COSV99780675; called by muse, mutect2, varscan2
- AKAP4 | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62074484; called by muse, mutect2, varscan2
- AL121899.2 | c.1393T>G p.S465A | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV67350705; called by muse, mutect2, varscan2
- ALOXE3 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs144996877, COSV59074427; called by muse, mutect2, varscan2
- ALPK1 | c.1400G>T p.C467F | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV51585189; called by muse, mutect2, varscan2
- AMOTL1 | c.1980A>C p.E660D | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV58566798; called by muse, mutect2, varscan2
- ANAPC7 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 140/402 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs372040468; called by muse, mutect2, varscan2
- ANGPT2 | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV57337104; called by muse, mutect2, varscan2
- ANKAR | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs757357867, COSV55612940; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKRD24 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV53670859, COSV53671202; called by muse, varscan2
- AOC3 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs781215948, COSV53826712; called by muse, mutect2, varscan2
- AP1G2 | c.272T>C p.M91T | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58112806; called by muse, mutect2, varscan2
- AP3B1 | c.2762A>G p.E921G | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs753810749, COSV54876118, COSV54884208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APMAP | c.403T>G p.F135V | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99468084; called by muse, mutect2, varscan2
- APOA5 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 99/301 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs750842108, CD105008, COSV57063244; called by muse, mutect2, varscan2
- AQP4 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67218677; called by muse, mutect2, varscan2
- ARFIP2 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV54446838; called by muse, mutect2, varscan2
- ARHGAP21 | c.4094T>C p.I1365T | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV57605886; called by muse, mutect2, varscan2
- ARHGEF12 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 50/167 reads (30%) | catalogued as COSV100754562; called by muse, mutect2, varscan2
- ARHGEF39 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV58397176; called by muse, mutect2, varscan2
- ARHGEF9 | c.1130A>G p.E377G | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV53638475; called by muse, mutect2, varscan2
- ARID1B | c.5680A>G p.I1894V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV99266621; called by muse, mutect2, varscan2
- ARMC2 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs775864051, COSV64551289; called by muse, mutect2, varscan2
- ART5 | c.679dup p.H227Pfs*2 | Frame Shift Ins (INS) | VAF 12/51 reads (24%) | catalogued as rs748137393; called by mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 82/258 reads (32%) | catalogued as rs772181094; called by mutect2, varscan2
- ASAP1 | c.1091A>G p.Q364R | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100726762; called by muse, mutect2
- ASB5 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56670786, COSV56671107; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 132/231 reads (57%) | catalogued as rs747570359; called by mutect2, varscan2
- ASH1L | c.8273C>T p.T2758I (on ENST00000368346 / NM_001366177.2; = p.T2753I on NM_018489.3) | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.966); catalogued as rs202229139, COSV64208170; called by muse, mutect2, varscan2
- ASMT | c.857T>C p.L286P (on ENST00000381229; = p.L314P on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/681 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV67109867; called by muse, mutect2, varscan2
- ATAD5 | c.2593A>G p.T865A | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58974826, COSV58977964; called by muse, mutect2, varscan2
- ATG4A | c.295T>G p.W99G | Missense Mutation (SNP) | VAF 114/217 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV58965669; called by muse, mutect2, varscan2
- ATM | c.6179G>A p.R2060H | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs376521407, COSV53745356; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ATP13A2 | c.2171T>C p.M724T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs774661817, COSV58700812; called by muse, mutect2, varscan2
- ATP2B4 | c.3174G>T p.K1058N | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.233); catalogued as COSV58178076; called by muse, mutect2, varscan2
- ATP4A | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs754720662, COSV52868160; called by muse, mutect2, varscan2
- ATP6V0D2 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs774964031, COSV53413041; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as COSV52269525; called by muse, mutect2, varscan2
- ATXN2 | c.3933G>T p.Q1311H (on ENST00000550104; = p.Q1151H on NM_002973.4) | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57983468; called by muse, mutect2, varscan2
- ATXN7L2 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs185034916, COSV60204908; called by muse, mutect2, varscan2
- AVIL | c.1936G>A p.V646M | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1460576474, COSV57681919; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1134G>T p.W378C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50056092; called by muse, mutect2, varscan2
- BAZ2B | c.816A>T p.E272D | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.026); catalogued as rs1402517839, COSV58601173; called by muse, mutect2, varscan2
- BBS7 | c.1063A>C p.K355Q | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV99144786; called by muse, mutect2
- BBS7 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99144787; called by muse, mutect2
- BDNF | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.989); catalogued as COSV59235010; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 69/355 reads (19%) | catalogued as rs752427670; called by mutect2, varscan2
- BEX5 | c.113T>G p.V38G | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61328459; called by muse, varscan2
- BMPR1A | c.1379T>C p.M460T | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as rs758309022, COSV64406206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR1B | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs377000102, COSV52777569, COSV52777734; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 56/198 reads (28%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BOD1L1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs768340636, COSV50012031; called by muse, mutect2, varscan2
- BPIFB4 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs779054648, COSV64950908, COSV64951234; called by muse, mutect2, varscan2
- BPTF | c.3259del p.I1087* | Frame Shift Del (DEL) | VAF 53/188 reads (28%) | catalogued as rs757520968; called by mutect2, varscan2
- BRINP3 | c.445A>T p.I149F | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100818221, COSV66524697; called by muse, mutect2, varscan2
- BSN | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV99607020; called by muse, mutect2, varscan2
- BTBD16 | c.729dup p.T244Dfs*26 | Frame Shift Ins (INS) | VAF 11/48 reads (23%) | catalogued as rs774408792; called by pindel, varscan2
- BTBD9 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58426293; called by muse, mutect2, varscan2
- BTN1A1 | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55067764; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C2orf42 | c.1542G>T p.E514D | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV100033624; called by muse, varscan2
- C6orf118 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 107/189 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV57815181; called by muse, mutect2, varscan2
- C6orf136 | c.557G>A p.R186H (on ENST00000376473 / NM_001109938.3; = p.R52H on NM_145029.4) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs376377195; called by muse, mutect2, varscan2
- C8B | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64776352; called by muse, mutect2, varscan2
- CABIN1 | c.1912T>C p.Y638H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54081986; called by muse, mutect2, varscan2
- CACHD1 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.972); catalogued as rs753954534, COSV51553557; called by muse, mutect2, varscan2
- CACNA1C | c.6442G>A p.A2148T (on ENST00000399634 / NM_001167625.1; = p.A2077T on NM_000719.7) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs745761632, COSV59721006; called by muse, varscan2
- CACNA1D | c.1370_1372del p.G457del | In Frame Del (DEL) | VAF 50/238 reads (21%) | catalogued as rs767282463; called by pindel, varscan2
- CACNA1E | c.5794C>T p.R1932W | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs776416674, COSV62396001, COSV62413229; called by muse, mutect2, varscan2
- CACNA1F | c.4027G>A p.V1343I | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs151203138, COSV59904563; called by muse, mutect2, varscan2
- CACNA1F | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs782280160, COSV59904568; called by muse, mutect2, varscan2
- CACNG1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs918445063, COSV56826836; called by muse, mutect2, varscan2
- CAD | c.4537G>A p.A1513T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.335); catalogued as rs553621458, COSV99254278; called by muse, mutect2, varscan2
- CADM1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 104/196 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs1471338171, COSV59010737; called by muse, mutect2, varscan2
- CADM2 | c.598G>A p.A200T (on ENST00000407528 / NM_001167674.2; = p.A202T on NM_153184.4) | Missense Mutation (SNP) | VAF 120/334 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.342); catalogued as rs1333409387, COSV67375650; called by muse, mutect2, varscan2
- CADPS | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51867195, COSV51886367; called by muse, mutect2, varscan2
- CALB2 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV56939507; called by muse, mutect2, varscan2
- CAPRIN2 | c.3057G>T p.E1019D | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51832645; called by muse, mutect2, varscan2
- CASD1 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 98/601 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51972587; called by muse, mutect2, varscan2
- CCAR1 | c.1130A>G p.D377G | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV56269953; called by muse, mutect2, varscan2
- CCDC120 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs781816554; called by muse, varscan2
- CCDC144A | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 277/898 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as COSV60698451, COSV60698573; called by muse, mutect2, varscan2
- CCDC148 | c.1251del p.I418* | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs758917400; called by mutect2, varscan2
- CCDC15 | c.581dup p.S196Ifs*6 | Frame Shift Ins (INS) | VAF 41/148 reads (28%) | catalogued as rs759789184; called by mutect2, varscan2
- CCDC170 | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV53341000; called by muse, mutect2
- CCDC18 | c.774dup p.V259Sfs*3 | Frame Shift Ins (INS) | VAF 168/508 reads (33%) | catalogued as rs746565576; called by mutect2, varscan2
- CCDC77 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280483392, COSV53473066; called by muse, mutect2, varscan2
- CCR8 | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as COSV58337254; called by muse, mutect2, varscan2
- CCT8L2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs368696107; called by muse, mutect2, varscan2
- CD200R1L | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV68004284; called by muse, mutect2, varscan2
- CD34 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as COSV60413034; called by muse, mutect2, varscan2
- CDC25B | c.1028A>G p.D343G (on ENST00000245960 / NM_021873.3; = p.D329G on NM_004358.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55656750; called by muse, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH4 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs759379228, COSV64645806; called by muse, varscan2
- CDH6 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 232/515 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54066466, COSV54070403; called by muse, mutect2, varscan2
- CDON | c.2625del p.S875Rfs*8 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | catalogued as COSV54998106; called by mutect2, pindel, varscan2
- CEACAM18 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs371514477, COSV67282652; called by muse, mutect2, varscan2
- CEP164 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV54041486; called by muse, mutect2, varscan2
- CEP192 | c.3874G>T p.G1292* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as COSV58064568; called by muse, mutect2, varscan2
- CFAP44 | c.14A>T p.D5V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as COSV55611570; called by muse, mutect2, varscan2
- CFAP47 | c.2819C>T p.A940V | Missense Mutation (SNP) | VAF 158/364 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs1339667296, COSV52884827; called by muse, mutect2, varscan2
- CFAP53 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV68351986; called by muse, mutect2, varscan2
- CFAP94 | c.1223T>C p.I408T (on ENST00000320267 / NM_001352064.2; = p.I414T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV57232344; called by muse, mutect2, varscan2
- CGN | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs762534512, COSV54970081; called by muse, mutect2, varscan2
- CHD6 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV58557334; called by muse, mutect2, varscan2
- CHPF | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs552002112, COSV60534800; called by muse, mutect2, varscan2
- CHST14 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.833); catalogued as rs1207935361, COSV60378824; called by muse, mutect2, varscan2
- CHST5 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs769565596, COSV60337156; called by muse, mutect2, varscan2
- CIC | c.859G>T p.G287W | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50573264; called by muse, varscan2
- CIT | c.2984G>A p.R995H | Missense Mutation (SNP) | VAF 195/544 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs538911447, COSV55869410; called by muse, mutect2, varscan2
- CIT | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1475867999, COSV55869422; called by muse, mutect2, varscan2
- CLCF1 | c.30dup p.M11Dfs*35 | Frame Shift Ins (INS) | VAF 36/114 reads (32%) | catalogued as rs1181051617; called by mutect2, pindel, varscan2
- CLCN5 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs1557193914; called by muse, mutect2
- CLDN8 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54525961; called by muse, mutect2, varscan2
- CLEC12A | c.223dup p.M75Nfs*9 | Frame Shift Ins (INS) | VAF 34/110 reads (31%) | catalogued as rs756570750; called by mutect2, varscan2
- CLEC14A | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs558964656, COSV60562592; called by muse, mutect2, varscan2
- CLEC4G | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as rs770488586; called by muse, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 32/123 reads (26%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPB | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV53629998; called by muse, mutect2, varscan2
- CLSTN2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs766373799, COSV71719763; called by muse, mutect2, varscan2
- CLYBL | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs200083846, COSV59221946; called by muse, mutect2, varscan2
- CMYA5 | c.4226A>G p.E1409G | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV71406037; called by muse, mutect2, varscan2
- CNKSR1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs751252460, COSV64163060; called by muse, mutect2, varscan2
- CNNM4 | c.1351T>G p.F451V | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); catalogued as COSV65660942; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 41/124 reads (33%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 38/96 reads (40%) | catalogued as rs374805044; called by mutect2, varscan2
- COBLL1 | c.677T>C p.L226P (on ENST00000392717; = p.L188P on NM_014900.5) | Missense Mutation (SNP) | VAF 106/303 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1457740449, COSV52068159; called by muse, mutect2, varscan2
- COG7 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs764545607, COSV56150354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL1A1 | c.4183G>T p.E1395* | Nonsense Mutation (SNP) | VAF 98/298 reads (33%) | catalogued as COSV56805168; called by muse, varscan2
- COL1A1 | c.3926A>G p.Q1309R | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56805179; called by muse, mutect2, varscan2
- COL1A1 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56804614, COSV56805195; called by muse, mutect2, varscan2
- COL1A2 | c.3744G>T p.K1248N | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV51958470, COSV51964873; called by muse, mutect2, varscan2
- COL4A4 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV61632394; called by muse, mutect2, varscan2
- COQ8B | c.20del p.G7Afs*69 | Frame Shift Del (DEL) | VAF 69/137 reads (50%) | catalogued as rs763451274; called by mutect2, varscan2
- CORIN | c.2917T>C p.Y973H | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56691766; called by muse, mutect2, varscan2
- CORO6 | c.925T>C p.F309L | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs1248584728, COSV61470902; called by muse, mutect2, varscan2
- COX10 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV55405120; called by muse, mutect2, varscan2
- CPNE4 | c.326A>C p.D109A | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV70194455; called by muse, mutect2, varscan2
- CPXM2 | c.2131del p.A711Pfs*35 | Frame Shift Del (DEL) | VAF 67/226 reads (30%) | catalogued as COSV99581978; called by mutect2, pindel, varscan2
- CRACD | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1391473006, COSV51714583; called by muse, mutect2, varscan2
- CRADD | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60553600; called by muse, mutect2, varscan2
- CREBBP | c.2516A>G p.Q839R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.418); catalogued as COSV52124411; called by muse, mutect2, varscan2
- CRYBG1 | c.5890C>T p.R1964* | Nonsense Mutation (SNP) | VAF 48/178 reads (27%) | catalogued as rs373572080, COSV64812540; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSMD1 | c.2787T>A p.A929= (on ENST00000520002; = p.A928= on NM_033225.6) | Splice Region (SNP) | VAF 22/48 reads (46%) | catalogued as COSV59326523; called by muse, mutect2, varscan2
- CSMD2 | c.4210G>A p.G1404S | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs200976511, COSV53914025; called by muse, mutect2, varscan2
- CSMD3 | c.8361G>T p.L2787F (on ENST00000297405 / NM_001363185.1; = p.L2618F on NM_052900.3) | Missense Mutation (SNP) | VAF 94/183 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as COSV52185633; called by muse, mutect2, varscan2
- CSMD3 | c.7223C>T p.T2408M (on ENST00000297405 / NM_001363185.1; = p.T2304M on NM_052900.3) | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs370458785; called by muse, mutect2, varscan2
- CSNK1A1L | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.363); catalogued as COSV65789716; called by muse, mutect2, varscan2
- CTNNA1 | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV57074133; called by muse, mutect2, varscan2
- CTNNA2 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.625); catalogued as COSV63568759; called by muse, mutect2, varscan2
- CTNNA3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs1195868563, COSV65583983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTR9 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs780976546, COSV63727691, COSV63728320, COSV63728637; called by muse, mutect2, varscan2
- CUL2 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV66079291; called by muse, mutect2, varscan2
- CUL9 | c.1292G>A p.W431* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as rs772155541, COSV52728749; called by muse, mutect2, varscan2
- CUX2 | c.4229T>A p.V1410E | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV55632727; called by muse, mutect2, varscan2
- CWC27 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751858333, COSV66885913, COSV66885937; called by muse, mutect2, varscan2
- CYFIP2 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV59036688, COSV59038387; called by muse, mutect2, varscan2
- CYP2A13 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 79/216 reads (37%) | catalogued as COSV57837912; called by muse, mutect2, varscan2
- DARS2 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1277759672, COSV53407129; called by muse, mutect2, varscan2
- DCLK1 | c.1408-1G>A p.X470_splice | Splice Site (SNP) | VAF 37/156 reads (24%) | catalogued as COSV55189781, COSV99708696, COSV99711209; called by muse, mutect2, varscan2
- DCN | c.849A>C p.R283S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99271694; called by muse, mutect2, varscan2
- DCST1 | c.1408C>G p.L470V | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs202162660, COSV55063674; called by muse, mutect2, varscan2
- DDX19A | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56359968; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 85/161 reads (53%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX5 | c.1358T>C p.V453A | Missense Mutation (SNP) | VAF 191/589 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56747738, COSV99858180; called by muse, mutect2, varscan2
- DDX56 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV51836667; called by muse, mutect2, varscan2
- DDX58 | c.1487T>C p.L496S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV101152373; called by muse, varscan2
- DENND4A | c.4322A>G p.Y1441C | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV71265889; called by muse, mutect2, varscan2
- DENND5B | c.2360G>T p.R787M | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60902697, COSV60908908; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DHRS7C | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV57650855; called by muse, mutect2, varscan2
- DIDO1 | c.2214+2T>C p.X738_splice | Splice Site (SNP) | VAF 37/132 reads (28%) | catalogued as COSV99824453; called by muse, mutect2, varscan2
- DLG5 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748210887, COSV64948254; called by muse, mutect2, varscan2
- DLG5 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV100967195; called by muse, mutect2, varscan2
- DMD | c.1909A>G p.T637A | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55872433; called by muse, mutect2, varscan2
- DMKN | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV60086400; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 45/138 reads (33%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.8837C>T p.A2946V (on ENST00000409039; = p.A2885V on NM_207437.3) | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs201720388, COSV68994148; called by muse, mutect2, varscan2
- DNAH17 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1321412708, COSV101101190; called by muse, varscan2
- DNAH8 | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs781704190, COSV59446862; called by muse, mutect2, varscan2
- DNAI1 | c.82-2A>G p.X28_splice | Splice Site (SNP) | VAF 66/187 reads (35%) | catalogued as COSV99646496; called by muse, mutect2, varscan2
- DNAJB4 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV66131594; called by muse, mutect2, varscan2
- DNAJC11 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 50/198 reads (25%) | catalogued as rs999766150, COSV53786833; called by muse, mutect2, varscan2
- DNAJC22 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101222492; called by muse, mutect2, varscan2
- DNAJC8 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 107/235 reads (46%) | catalogued as rs757585832, COSV55281620; called by muse, mutect2, varscan2
- DNER | c.1878C>A p.H626Q | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV59166660; called by muse, mutect2, varscan2
- DNHD1 | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV54436051; called by muse, mutect2, varscan2
- DOCK2 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56953545; called by muse, mutect2, varscan2
- DOCK2 | c.4045G>A p.G1349S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56959556; called by muse, mutect2, varscan2
- DOCK3 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as rs766088466, COSV56522340; called by muse, mutect2, varscan2
- DOCK3 | c.4123T>C p.C1375R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV56522351; called by muse, mutect2, varscan2
- DOCK9 | c.4002dup p.T1335Yfs*4 (on ENST00000376460 / NM_001366676.2; = p.T1336Yfs*4 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 108/374 reads (29%) | catalogued as rs1344550381; called by mutect2, varscan2
- DOK5 | c.899C>G p.P300R | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV52819240, COSV52820421, COSV52823946; called by muse, mutect2, varscan2
- DPF1 | c.476T>G p.L159R | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.223); catalogued as COSV62792506; called by muse, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DSG1 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57135430; called by muse, mutect2, varscan2
- DST | c.20510G>A p.R6837H (on ENST00000361203 / NM_001374722.1; = p.R4534H on NM_015548.5) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs576138885, COSV55015580; called by mutect2, varscan2
- DUOXA2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs753835283, COSV50993036; called by muse, mutect2, varscan2
- DZIP3 | c.2095A>G p.S699G | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV64312145; called by muse, mutect2, varscan2
- E2F8 | c.1380A>C p.K460N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV51463631; called by muse, mutect2, varscan2
- ECSIT | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as rs778037100, COSV52939464; called by muse, mutect2, varscan2
- ECT2L | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as COSV100871733; called by muse, mutect2, varscan2
- EDN3 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV61108053; called by muse, mutect2, varscan2
- EEPD1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs140394885; called by muse, mutect2, varscan2
- EIF2AK3 | c.1847A>T p.D616V | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57547938; called by muse, mutect2, varscan2
- EIF2AK4 | c.2567dup p.L856Ffs*4 | Frame Shift Ins (INS) | VAF 63/153 reads (41%) | catalogued as rs35250897; called by mutect2, varscan2
- ELAPOR1 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV64040475; called by muse, mutect2, varscan2
- ELAPOR2 | c.1208A>G p.Y403C (on ENST00000450689 / NM_001142749.3; = p.Y236C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV51887096; called by muse, mutect2, varscan2
- ELAVL3 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV63646039; called by muse, mutect2, varscan2
- EML5 | c.3313A>G p.S1105G | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV61345808; called by muse, mutect2, varscan2
- ENKD1 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV54667736; called by muse, mutect2, varscan2
- ENTR1 | c.574G>A p.A192T (on ENST00000357365 / NM_001039707.2; = p.A169T on NM_006643.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs746354290; called by muse, varscan2
- EPC1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 17/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53925441; called by muse, mutect2
- EPHA3 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as rs758342526, COSV60706580; called by muse, mutect2, varscan2
- EPHA7 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as COSV65183015; called by muse, mutect2, varscan2
- EPRS1 | c.1225A>G p.I409V | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1433471935, COSV65099055; called by muse, mutect2, varscan2
- EPS8L1 | c.2021C>T p.A674V (on ENST00000201647 / NM_133180.3; = p.A547V on NM_017729.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs995815801, COSV52381827; called by muse, mutect2, varscan2
- ERBB4 | c.1590G>T p.R530S | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.059); catalogued as COSV53505008, COSV53510629, COSV53533788; called by muse, varscan2
- ERICH3 | c.987A>C p.K329N | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV58607059; called by muse, mutect2, varscan2
- ESPL1 | c.5092C>T p.R1698C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1473544704, COSV57759574; called by muse, mutect2, varscan2
- ESPL1 | c.5712G>T p.W1904C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99228763; called by muse, mutect2, varscan2
- ETF1 | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV62127343; called by muse, mutect2, varscan2
- ETV6 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs745867456, COSV67150238; called by muse, mutect2, varscan2
- EXOC6B | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs201814463, COSV55555703; called by muse, varscan2
- F13A1 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV53558729, COSV99343827; called by muse, mutect2, varscan2
- FABP4 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.5); catalogued as COSV56269018; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 32/170 reads (19%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 51/138 reads (37%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM111A | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs748374095, COSV64655368; called by muse, mutect2, varscan2
- FAM149A | c.1040A>C p.H347P (on ENST00000356371 / NM_001367768.2; = p.H56P on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV57027424; called by muse, mutect2, varscan2
- FAM209A | c.469T>A p.Y157N | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54767090; called by muse, mutect2, varscan2
- FAM20B | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 33/129 reads (26%) | catalogued as rs773926718, COSV55380376; called by muse, mutect2, varscan2
- FAM47C | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs145034356, COSV100792224, COSV63724689; called by muse, mutect2, varscan2
- FANCB | c.1547C>A p.S516Y | Missense Mutation (SNP) | VAF 58/305 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV60759963; called by muse, mutect2, varscan2
- FANCF | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs758608960, COSV59416340; called by mutect2, varscan2
- FANCM | c.4868T>G p.V1623G | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV57501351; called by muse, mutect2, varscan2
- FAT2 | c.12127del p.D4043Tfs*8 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | catalogued as COSV99941906; called by mutect2, pindel, varscan2
- FAT2 | c.10436C>A p.P3479Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs372161810, COSV55819509, COSV55820103; called by muse, mutect2, varscan2
- FAT3 | c.2056A>G p.T686A | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53112608; called by muse, mutect2, varscan2
- FAT3 | c.2143T>G p.F715V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV53112635, COSV53165730; called by muse, mutect2, varscan2
- FAT4 | c.12238T>C p.C4080R | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100627027; called by muse, mutect2, varscan2
- FAT4 | c.13434del p.K4479Rfs*15 | Frame Shift Del (DEL) | VAF 46/142 reads (32%) | catalogued as COSV58708215; called by mutect2, pindel, varscan2
- FBN2 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV52514372; called by muse, mutect2, varscan2
- FBXO16 | c.26del p.N9Tfs*11 | Frame Shift Del (DEL) | VAF 138/457 reads (30%) | catalogued as rs770129495; called by mutect2, pindel, varscan2
- FBXO30 | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 158/286 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52791300; called by muse, mutect2, varscan2
- FBXO32 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756822475, COSV54891111; called by muse, mutect2, varscan2
- FCGBP | c.447del p.G150Afs*25 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs765680504; called by mutect2, pindel, varscan2
- FCN2 | c.230del p.P77Lfs*23 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs1339990522; called by mutect2, varscan2
- FCRL3 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 140/336 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs767160539, COSV63841683; called by muse, mutect2, varscan2
- FCRL3 | c.1172G>T p.R391M | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV63841692; called by muse, mutect2, varscan2
- FHOD3 | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 60/418 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57173747; called by muse, mutect2, varscan2
- FHOD3 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs960627486, COSV57173045, COSV99942301; called by muse, mutect2, varscan2
- FLT1 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV56728367, COSV56741828; called by muse, mutect2, varscan2
- FMNL1 | c.911A>G p.H304R | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.085); catalogued as COSV58957033; called by muse, mutect2, varscan2
- FNBP4 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 141/398 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55448750; called by muse, mutect2, varscan2
- FOSL1 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 99/270 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57028794; called by muse, varscan2
- FOXD4L5 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs1245807826; called by mutect2, varscan2
- FSTL1 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 149/397 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV55233816; called by muse, mutect2, varscan2
- FTHL17 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs748357093, COSV63266985; called by muse, mutect2, varscan2
- FUT3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757862405, COSV54605943; called by muse, mutect2, varscan2
- FUT6 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 109/605 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs375534466; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 40/105 reads (38%) | catalogued as rs756304971; called by mutect2, varscan2
- FXR2 | c.1619dup p.A541Sfs*14 | Frame Shift Ins (INS) | VAF 25/78 reads (32%) | catalogued as rs753982098; called by mutect2, varscan2
- FZD7 | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV53810127; called by muse, mutect2, varscan2
- GABPB2 | c.1112A>G p.Y371C | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV64460916; called by muse, mutect2, varscan2
- GABRA5 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59485712; called by muse, mutect2, varscan2
- GABRB3 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54665030; called by muse, varscan2
- GABRG3 | c.1370A>G p.N457S | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV61518657; called by muse, mutect2, varscan2
- GAD2 | c.1337G>A p.C446Y | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52157790, COSV52167358; called by muse, mutect2, varscan2
- GALNT17 | c.1647C>A p.Y549* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV61163084; called by muse, mutect2, varscan2
- GAS8 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs1187785972; called by muse, mutect2, varscan2
- GATA1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64962318; called by muse, mutect2, varscan2
- GBA2 | c.1535A>G p.H512R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV62305858; called by muse, mutect2, varscan2
- GBA3 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV72438142; called by muse, mutect2, varscan2
- GBP2 | c.1254_1256del p.E418del | In Frame Del (DEL) | VAF 76/196 reads (39%) | catalogued as rs765107402; called by pindel, varscan2
- GDF15 | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV53250542, COSV53251133; called by muse, mutect2, varscan2
- GFOD2 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV52057974; called by muse, mutect2, varscan2
- GFPT2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs370818985; called by muse, mutect2, varscan2
- GLB1L2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs776437306, COSV60277605; called by muse, mutect2, varscan2
- GLB1L3 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs755934137, COSV68392765; called by muse, mutect2, varscan2
- GLRB | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV52417025; called by muse, mutect2, varscan2
- GNA14 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 132/349 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59023935, COSV59029715; called by muse, mutect2, varscan2
- GNB1 | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV101060726; called by muse, mutect2, varscan2
- GNL1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs757866378, COSV64835225; called by muse, mutect2, varscan2
- GOT1L1 | c.870dup p.N291Qfs*89 | Frame Shift Ins (INS) | VAF 25/81 reads (31%) | catalogued as rs768946390; called by mutect2, varscan2
- GPAA1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs369617537, COSV60155766; called by muse, mutect2, varscan2
- GPD1L | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV56990135; called by muse, mutect2, varscan2
- GPHN | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as rs530173903, COSV59480870; called by muse, mutect2, varscan2
- GPR149 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV67667416; called by muse, mutect2, varscan2
- GPR52 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 183/570 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1453719313, COSV52296355; called by muse, mutect2, varscan2
- GRAMD2B | c.1288A>G p.N430D | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV53507592; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK4 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.76); PolyPhen possibly damaging (0.699); catalogued as rs1191383047, COSV70802377, COSV70802702; called by muse, mutect2, varscan2
- GRIN3A | c.3176G>A p.R1059Q | Missense Mutation (SNP) | VAF 101/294 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs199945164, COSV62453970; called by muse, mutect2, varscan2
- GRIPAP1 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV64552099; called by muse, mutect2
- GRM1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51112717; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2566G>A p.D856N (on ENST00000265755 / NM_016328.3; = p.D841N on NM_005685.4) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs782620258, COSV56086567, COSV56090067; called by muse, mutect2, varscan2
- GUCA1A | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 53/121 reads (44%) | catalogued as rs1356867260, COSV50004198; called by muse, mutect2, varscan2
- GUCY1A1 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.042); catalogued as COSV99636961; called by muse, mutect2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 88/372 reads (24%) | catalogued as COSV54945907; called by mutect2, varscan2
- GYPB | c.61A>C p.S21R | Missense Mutation (SNP) | VAF 183/1005 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs180889318; called by muse, varscan2
- HACE1 | c.1478G>T p.R493I | Missense Mutation (SNP) | VAF 33/325 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53502589; called by muse, varscan2
- HAS1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1447720912; called by muse, mutect2, varscan2
- HAUS5 | c.1573C>A p.L525M | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs1167573969, COSV52547983; called by muse, mutect2, varscan2
- HDHD3 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs772718812, COSV53057216; called by muse, mutect2, varscan2
- HECTD4 | c.13216G>A p.A4406T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV66392363; called by muse, mutect2, varscan2
- HECTD4 | c.7261G>A p.V2421I | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs768805905, COSV66392366; called by muse, mutect2, varscan2
- HELB | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1267788399, COSV56071957; called by muse, mutect2, varscan2
- HELQ | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751377136, COSV55025334; called by muse, mutect2, varscan2
- HERC2 | c.13478T>G p.L4493R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55324519; called by muse, mutect2, varscan2
- HERC2 | c.4282C>T p.P1428S | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.979); catalogued as COSV55324530; called by muse, mutect2, varscan2
- HERC6 | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1478737280, COSV52030267; called by muse, mutect2, varscan2
- HGD | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99380526; called by muse, mutect2, varscan2
- HGF | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949909; called by muse, varscan2
- HLA-G | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 63/336 reads (19%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.506); catalogued as COSV64405721; called by muse, mutect2, varscan2
- HLCS | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV60793784; called by muse, mutect2, varscan2
- HMOX1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768800478, COSV53339862; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 81/286 reads (28%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXD3 | c.305del p.G102Vfs*9 | Frame Shift Del (DEL) | VAF 29/95 reads (31%) | catalogued as COSV99980268; called by mutect2, pindel, varscan2
- HSD17B10 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV51448069; called by muse, mutect2, varscan2
- HSF2 | c.648A>G p.I216M | Missense Mutation (SNP) | VAF 108/203 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV63773938; called by muse, mutect2, varscan2
- HSPA9 | c.1665A>C p.K555N | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.495); catalogued as COSV51864491; called by muse, mutect2, varscan2
- HTR1F | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 93/306 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60389746; called by muse, mutect2, varscan2
- HTT | c.6869G>T p.G2290V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV61862433; called by muse, mutect2, varscan2
- HUWE1 | c.4223G>T p.R1408L | Missense Mutation (SNP) | VAF 128/367 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV53346175; called by muse, mutect2, varscan2
- HYOU1 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as rs782034654, COSV68215840; called by muse, mutect2, varscan2
- IARS2 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV56959868; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 41/120 reads (34%) | catalogued as rs747841314; called by mutect2, varscan2
- ICAM1 | c.272T>C p.M91T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV53425146; called by muse, mutect2, varscan2
- IFI27L2 | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 21/479 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53128758; called by muse, mutect2
- IFT172 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327376049, COSV53133903; called by muse, mutect2, varscan2
- IFT80 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs754818191, COSV58447770; called by muse, mutect2, varscan2
- IGFBP3 | c.746A>T p.K249M | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51872434; called by muse, mutect2, varscan2
- IGHV2-70 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.743); catalogued as rs61732216; called by muse, mutect2
- IKZF2 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 59/167 reads (35%) | catalogued as COSV59578755, COSV59584959; called by muse, mutect2, varscan2
- IL21R | c.1350G>C p.K450N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV61969444, COSV61970509; called by muse, mutect2
- ILVBL | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54619754; called by muse, mutect2, varscan2
- IMMT | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV54487100; called by muse, mutect2, varscan2
- INPP5F | c.788del p.P263Lfs*7 | Frame Shift Del (DEL) | VAF 60/197 reads (30%) | catalogued as rs750419826; called by mutect2, pindel, varscan2
- INPPL1 | c.2950C>A p.P984T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs892095304, COSV53353388, COSV53355693; called by muse, mutect2, varscan2
- INSR | c.1750A>G p.K584E | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV57163138; called by muse, mutect2, varscan2
- INTS10 | c.1613C>A p.S538* | Nonsense Mutation (SNP) | VAF 67/193 reads (35%) | catalogued as COSV67604249; called by muse, mutect2, varscan2
- INTS13 | c.1594A>G p.M532V | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs1403909653, COSV53902698; called by muse, mutect2, varscan2
- IQCF1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778155817, COSV58823457; called by muse, mutect2, varscan2
- IQSEC1 | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs777516598; called by muse, mutect2, varscan2
- ITGAM | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147195093; called by muse, mutect2, varscan2
- ITGB2 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV56610275; called by muse, mutect2, varscan2
- ITIH5 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs112992012; called by muse, mutect2, varscan2
- ITIH6 | c.2728A>C p.S910R | Missense Mutation (SNP) | VAF 109/344 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54489273, COSV54495560; called by muse, mutect2, varscan2
- ITLN2 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV63537780; called by muse, mutect2, varscan2
- ITPRID1 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60075147; called by muse, mutect2, varscan2
- JAKMIP2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54599965; called by muse, mutect2, varscan2
- JCAD | c.3595A>T p.K1199* | Nonsense Mutation (SNP) | VAF 45/117 reads (38%) | catalogued as COSV64759716; called by muse, mutect2, varscan2
- KALRN | c.7753G>A p.V2585M (on ENST00000360013 / NM_001024660.4; = p.V888M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373744782, COSV52248952; called by muse, mutect2, varscan2
- KANSL1 | c.2762C>T p.A921V (on ENST00000574590 / NM_001193465.2; = p.A922V on NM_015443.4) | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs1325326306, COSV52240617; called by muse, mutect2, varscan2
- KAT6B | c.5789C>T p.A1930V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as rs767826139, COSV54745244; called by muse, mutect2, varscan2
- KATNAL1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs762143192, COSV66063339; called by muse, mutect2, varscan2
- KATNIP | c.2884G>A p.A962T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs749729955, COSV55180953; called by muse, mutect2, varscan2
- KCNA3 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63901626; called by muse, mutect2, varscan2
- KCNA4 | c.1307A>G p.Q436R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV60252420; called by muse, mutect2, varscan2
- KCND2 | c.943T>C p.Y315H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV58580665; called by muse, mutect2, varscan2
- KCNH6 | c.2333G>A p.G778E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1040715870; called by muse, mutect2, varscan2
- KCNH7 | c.85T>A p.F29I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59791047; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 28/222 reads (13%) | catalogued as rs771351714; called by mutect2, varscan2
- KDM3B | c.3118A>G p.N1040D | Missense Mutation (SNP) | VAF 65/404 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58690845; called by muse, mutect2, varscan2
- KDM5A | c.4946A>T p.E1649V | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66992519; called by muse, mutect2, varscan2
- KIAA0232 | c.3226C>A p.L1076I | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV56925495; called by muse, mutect2, varscan2
- KIAA1109 | c.11859A>T p.K3953N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52674163; called by muse, mutect2, varscan2
- KIAA1522 | c.1831T>C p.F611L (on ENST00000373480 / NM_001198972.2; = p.F670L on NM_020888.3) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs748852883; called by muse, mutect2, varscan2
- KIAA1958 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs1218340281, COSV61723772; called by muse, mutect2, varscan2
- KIF13A | c.3392C>T p.A1131V | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV52451674; called by muse, mutect2, varscan2
- KIF14 | c.4444C>T p.Q1482* | Nonsense Mutation (SNP) | VAF 125/331 reads (38%) | catalogued as COSV66261841; called by muse, mutect2, varscan2
- KIF16B | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs368432617; called by muse, mutect2, varscan2
- KIF17 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140621013; called by muse, varscan2
- KIF7 | c.3886C>T p.R1296W | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs769783876, COSV51541735, COSV99177101; called by muse, mutect2, varscan2
- KIF9 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.633); catalogued as rs1193418986, COSV55518205, COSV55519636; called by muse, mutect2, varscan2
- KLC1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs926694130, COSV55808068; called by muse, mutect2, varscan2
- KLHL35 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs757064527, COSV66219631; called by muse, varscan2
- KLRK1 | c.336A>T p.Q112H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.192); catalogued as COSV53698590; called by muse, mutect2, varscan2
- KRT34 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs770889609, COSV67450643; called by muse, varscan2
- KRT40 | c.386T>A p.I129N | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.222); catalogued as rs199823333, COSV100898766; called by muse, mutect2, varscan2
- KRT74 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.765); catalogued as COSV59771502; called by muse, mutect2, varscan2
- KRTAP5-3 | c.89del p.G30Afs*236 | Frame Shift Del (DEL) | VAF 99/268 reads (37%) | catalogued as COSV101294515; called by mutect2, pindel, varscan2
- LACTB2 | c.258A>G p.I86M | Missense Mutation (SNP) | VAF 225/447 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV52567920; called by muse, mutect2, varscan2
- LAMB1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774870882, COSV55964026, COSV55964780; called by muse, mutect2
- LAMB2 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282468060, COSV59730632; called by muse, mutect2, varscan2
- LANCL1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV52065276; called by muse, varscan2
- LARP1B | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs187112542, COSV52797811; called by muse, mutect2, varscan2
- LCA5 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.874); catalogued as COSV63971408; called by muse, mutect2, varscan2
- LGI2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1197547219, COSV101180740, COSV66122851; called by muse, mutect2, varscan2
- LHX5 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as rs1398832644, COSV55663890, COSV99922410; called by muse, varscan2
- LIMK1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368498172; called by muse, mutect2
- LIPE | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1303057820, COSV54923008; called by muse, mutect2, varscan2
- LMBRD1 | c.1385G>T p.S462I (on ENST00000649011; = p.S440I on NM_018368.4) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV65297341; called by muse, mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | catalogued as rs748712732; called by mutect2, varscan2
- LNPEP | c.617A>C p.N206T | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1445612744, COSV51478106; called by muse, mutect2, varscan2
- LNX1 | c.1351G>A p.A451T (on ENST00000263925 / NM_001126328.3; = p.A355T on NM_032622.2) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.893); catalogued as COSV55785838; called by muse, mutect2, varscan2
- LPIN1 | c.2261T>C p.L754P | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773337013, COSV56765750; called by muse, mutect2, varscan2
- LRCH2 | c.1376T>C p.L459P | Missense Mutation (SNP) | VAF 226/445 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV57751239; called by muse, mutect2, varscan2
- LRP1B | c.12889G>T p.G4297* | Nonsense Mutation (SNP) | VAF 40/155 reads (26%) | catalogued as COSV67221952; called by muse, mutect2, varscan2
- LRP4 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.045); catalogued as rs1484210878, COSV66135922; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC37A3 | c.3912del p.K1304Nfs*11 | Frame Shift Del (DEL) | VAF 140/495 reads (28%) | catalogued as rs1261486978; called by mutect2, pindel, varscan2
- LRRC71 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 32/124 reads (26%) | catalogued as rs539763262, COSV61656242; called by muse, mutect2, varscan2
- LRRCC1 | c.3037dup p.T1013Nfs*7 | Frame Shift Ins (INS) | VAF 89/692 reads (13%) | catalogued as rs1288173822; called by mutect2, varscan2
- LRRFIP1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs201221434; called by muse, mutect2, varscan2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 76/231 reads (33%) | catalogued as rs756089224; called by mutect2, varscan2
- LRRTM4 | c.557dup p.L186Ffs*60 | Frame Shift Ins (INS) | VAF 70/232 reads (30%) | catalogued as rs760292106; called by mutect2, pindel, varscan2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 53/156 reads (34%) | catalogued as rs1301982151; called by mutect2, pindel, varscan2
- MACF1 | c.9100G>A p.A3034T | Missense Mutation (SNP) | VAF 116/392 reads (30%) | catalogued as rs1457801660, COSV57121973; called by muse, mutect2, varscan2
- MADD | c.2337del p.P781Lfs*34 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs1187192079; called by mutect2, pindel, varscan2
- MAGED1 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs200856189, COSV58515300; called by muse, mutect2, varscan2
- MAN2B1 | c.916T>C p.Y306H | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV55472063; called by muse, mutect2, varscan2
- MAN2C1 | c.2254del p.V752Cfs*60 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as COSV51229221; called by mutect2, varscan2
- MAP1B | c.5374T>C p.S1792P | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV57099330; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.54A>C p.E18D | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61010070; called by muse, mutect2, varscan2
- MAP2K4 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62257409, COSV62257489; called by muse, mutect2, varscan2
- MAP3K11 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs565087687, COSV58419698; called by muse, varscan2
- MAP7 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 85/652 reads (13%) | catalogued as COSV63419839; called by muse, mutect2, varscan2
- MASP1 | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV51459982; called by muse, mutect2, varscan2
- MC2R | c.275T>G p.L92R | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59618209; called by muse, mutect2, varscan2
- MCC | c.1751A>G p.K584R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.899); catalogued as rs747962564, COSV56729172; called by muse, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 56/107 reads (52%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM3AP | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs758105613, COSV52439947; called by muse, mutect2, varscan2
- MCOLN1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760754683, COSV51175649; called by muse, mutect2, varscan2
- MCTP2 | c.1820T>C p.L607P | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59144353; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 42/236 reads (18%) | catalogued as rs35107588; called by mutect2, pindel, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED26 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs778970108; called by muse, varscan2
- MED8 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs767122202, COSV51941017; called by muse, mutect2, varscan2
- MEGF10 | c.1739A>C p.N580T | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV57249408; called by muse, mutect2, varscan2
- MEI1 | c.1902C>A p.C634* | Nonsense Mutation (SNP) | VAF 74/196 reads (38%) | catalogued as COSV100299453; called by mutect2, varscan2
- METTL15 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV57720040; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 56/296 reads (19%) | catalogued as rs780635289; called by mutect2, varscan2
- MID1IP1 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 215/615 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV61230680; called by muse, mutect2, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 61/334 reads (18%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MITD1 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as COSV56806346; called by muse, mutect2, varscan2
- MKI67 | c.1177A>G p.R393G | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV64074460; called by muse, mutect2, varscan2
- MMP14 | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV61288335; called by muse, mutect2, varscan2
- MPC2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV54796740; called by muse, mutect2, varscan2
- MRGPRX3 | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV66933957; called by muse, mutect2, varscan2
- MRNIP | c.899G>A p.C300Y | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.275); catalogued as COSV52973129; called by muse, mutect2, varscan2
- MSH6 | c.3280T>C p.S1094P | Missense Mutation (SNP) | VAF 128/369 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.864); catalogued as COSV99314855; called by muse, varscan2
- MTCH1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV101010148; called by muse, mutect2, varscan2
- MTCL1 | c.4341dup p.P1448Afs*83 (on ENST00000306329 / NM_001378206.1; = p.P1129Afs*83 on NM_015210.4) | Frame Shift Ins (INS) | VAF 24/70 reads (34%) | catalogued as rs1194526003; called by mutect2, varscan2
- MTHFD2 | c.889+2T>C p.X297_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99902853; called by muse, mutect2
- MTO1 | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100940284; called by muse, mutect2, varscan2
- MTREX | c.1662C>A p.G554= | Splice Region (SNP) | VAF 88/243 reads (36%) | catalogued as COSV57926144; called by muse, mutect2, varscan2
- MTTP | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 193/516 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as COSV55505924; called by muse, mutect2, varscan2
- MUC16 | c.27722T>A p.V9241D | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.147); catalogued as COSV67467467; called by muse, mutect2, varscan2
- MUC16 | c.18374C>T p.A6125V | Missense Mutation (SNP) | VAF 223/542 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs775821896, COSV67467472; called by muse, mutect2, varscan2
- MUC16 | c.742T>A p.S248T | Missense Mutation (SNP) | VAF 96/254 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV67467481; called by muse, mutect2, varscan2
- MUC5B | c.2812G>A p.V938I | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs370402303; called by muse, varscan2
- MUC5B | c.6238A>G p.T2080A | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.48); catalogued as COSV71592121; called by muse, mutect2, varscan2
- MUC5B | c.7338_7339del p.E2447Vfs*233 | Frame Shift Del (DEL) | VAF 64/404 reads (16%) | catalogued as COSV71592122; called by mutect2, varscan2
- MUSK | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375737188, COSV51885774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MX1 | c.1473T>A p.N491K | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV55819339; called by muse, varscan2
- MYBBP1A | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs781028931, COSV54597858; called by muse, varscan2
- MYCBP2 | c.5932A>G p.T1978A (on ENST00000357337; = p.T2016A on NM_015057.5) | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs763650115, COSV62019950; called by muse, mutect2, varscan2
- MYH1 | c.2381C>A p.A794D | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1240226033, COSV56847886, COSV56848732; called by muse, mutect2, varscan2
- MYH10 | c.847A>C p.I283L | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99343855; called by muse, mutect2, varscan2
- MYH11 | c.4072G>A p.A1358T | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as COSV55553883; called by muse, mutect2, varscan2
- MYL6B | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52878829; called by muse, mutect2, varscan2
- MYO18A | c.2202G>T p.E734D | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100572675, COSV62866604; called by muse, mutect2, varscan2
- MYO18A | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs200761046, COSV62866613; called by muse, mutect2, varscan2
- MYO18B | c.7409G>A p.R2470H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs75632091, COSV59130736; called by muse, mutect2, varscan2
- MYO1F | c.3173A>C p.D1058A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV100596439; called by muse, mutect2, varscan2
- MYO1F | c.231G>A p.A77= | Splice Region (SNP) | VAF 13/96 reads (14%) | catalogued as rs774761610, COSV57795311; called by muse, mutect2, varscan2
- MYO3A | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs550530253, COSV56324161, COSV99781993; called by muse, mutect2, varscan2
- MYO3A | c.4663A>G p.S1555G | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV56331536; called by muse, mutect2, varscan2
- MYO5A | c.1727A>G p.Q576R | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.821); catalogued as COSV62560402; called by muse, mutect2, varscan2
- MYO9A | c.3769A>G p.R1257G | Missense Mutation (SNP) | VAF 68/430 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV61851341; called by muse, varscan2
- MYOD1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769475374; called by muse, varscan2
- NCKAP5 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs201814216, COSV58433575; called by muse, mutect2, varscan2
- NCKAP5 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58444713; called by muse, mutect2, varscan2
- NCOA3 | c.3092G>T p.R1031M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV100507017; called by muse, varscan2
- NCOA6 | c.6161C>T p.A2054V | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs367600298, COSV62863768; called by muse, mutect2, varscan2
- NCOA6 | c.6007C>T p.P2003S | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.196); catalogued as COSV62863775; called by muse, mutect2, varscan2
- NCOR1 | c.5033T>A p.I1678N | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV51975277; called by muse, mutect2, varscan2
- NDST3 | c.1616A>G p.N539S | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56614140; called by muse, mutect2, varscan2
- NEK6 | c.559A>C p.K187Q | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57217803; called by muse, mutect2, varscan2
- NEO1 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56071392; called by muse, mutect2, varscan2
- NETO2 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as rs759414615, COSV57452995; called by muse, mutect2, varscan2
- NEURL4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761211941, COSV59756469; called by muse, mutect2
- NID1 | c.1970T>C p.I657T | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs576525237, COSV51620595; called by muse, mutect2, varscan2
- NIN | c.3380del p.L1127Yfs*9 | Frame Shift Del (DEL) | VAF 58/264 reads (22%) | catalogued as COSV55385018; called by pindel, varscan2
- NIN | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 156/439 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769057633, COSV55384519, COSV99815014; called by muse, mutect2, varscan2
- NLN | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1423016963, COSV66765901; called by muse, mutect2, varscan2
- NLRC4 | c.1678C>A p.H560N | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61592742; called by muse, mutect2, varscan2
- NLRC4 | c.972A>C p.Q324H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61592747; called by muse, mutect2, varscan2
- NLRP10 | c.1686T>G p.D562E | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as COSV60780367; called by muse, mutect2, varscan2
- NLRP12 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs749659859, COSV60745823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP2 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763292353, COSV54755400; called by muse, mutect2, varscan2
- NMNAT2 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs1322178575, COSV54268512; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 104/270 reads (39%) | catalogued as rs759637346; called by mutect2, varscan2
- NPAP1 | c.462A>C p.Q154H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs761113460, COSV100275746, COSV61507229; called by muse, mutect2, varscan2
- NPM2 | c.539dup p.L181Afs*13 | Frame Shift Ins (INS) | VAF 169/532 reads (32%) | catalogued as rs770540772; called by mutect2, varscan2
- NPM3 | c.527del p.G176Afs*63 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | catalogued as rs771012365; called by mutect2, pindel, varscan2
- NPR2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1373177985, COSV61310800; called by muse, mutect2, varscan2
- NPR2 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1217392431, COSV61310807; called by muse, mutect2, varscan2
- NR4A2 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV59893932; called by muse, mutect2, varscan2
- NR5A2 | c.1306G>T p.A436S (on ENST00000367362 / NM_205860.3; = p.A390S on NM_003822.5) | Missense Mutation (SNP) | VAF 85/293 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52650559; called by muse, mutect2, varscan2
- NRCAM | c.3515G>A p.G1172D (on ENST00000379028 / NM_001371124.1; = p.G1051D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61037390; called by muse, mutect2, varscan2
- NRG2 | c.1376G>A p.S459N | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.097); catalogued as rs1217082793, COSV56829745; called by muse, mutect2, varscan2
- NRK | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 83/144 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767608122, COSV54597009; called by muse, mutect2, varscan2
- NRXN1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV68048135; called by muse, varscan2
- NSL1 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100875170; called by muse, mutect2, varscan2
- NSRP1 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV55933953, COSV55935275; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 46/182 reads (25%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTNG2 | c.686A>C p.N229T | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV62366759; called by muse, mutect2, varscan2
- NTPCR | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 197/451 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs1300702585, COSV64052520; called by muse, mutect2, varscan2
- NUGGC | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs778482764, COSV58434914; called by muse, mutect2, varscan2
- NUP153 | c.1011T>A p.N337K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV50449803; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 52/145 reads (36%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP98 | c.2131C>A p.H711N | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV61432327, COSV61433079; called by muse, mutect2, varscan2
- ODF1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.422); catalogued as rs759006752, COSV53432545; called by muse, mutect2, varscan2
- OGT | c.1583G>A p.G528D | Missense Mutation (SNP) | VAF 228/613 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV65480806; called by muse, mutect2, varscan2
- OR13A1 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV65572436; called by muse, mutect2, varscan2
- OR2B2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.696); catalogued as COSV57579748, COSV57580888; called by muse, mutect2, varscan2
- OR2C3 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV63575076; called by muse, mutect2, varscan2
- OR2F2 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101283850, COSV68832820; called by muse, mutect2, varscan2
- OR2M2 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62898399; called by muse, mutect2
- OR4B1 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV58882887; called by muse, mutect2, varscan2
- OR51A7 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV63788312, COSV63788913; called by muse, mutect2, varscan2
- OR51B5 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV56176093; called by muse, mutect2, varscan2
- OR51F1 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58579799; called by muse, mutect2, varscan2
- OR52B4 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV68768943; called by muse, mutect2, varscan2
- OR5T2 | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.021); catalogued as COSV57589287; called by muse, mutect2, varscan2
- OR6C65 | c.737T>G p.V246G | Missense Mutation (SNP) | VAF 202/595 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65568645; called by muse, mutect2, varscan2
- OR6C74 | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV59606506; called by muse, mutect2, varscan2
- OR8B2 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 214/652 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs141277809; called by muse, mutect2, varscan2
- ORC1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs779430952, COSV65363941; called by muse, mutect2, varscan2
- OSBPL11 | c.1768A>G p.N590D | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as COSV56174095; called by muse, mutect2, varscan2
- P2RX7 | c.652T>G p.F218V | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV55855315; called by muse, mutect2, varscan2
- P2RY2 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60776303; called by muse, mutect2, varscan2
- P4HA2 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV51325649; called by muse, mutect2, varscan2
- PALLD | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV54980907; called by muse, varscan2
- PAQR3 | c.22A>C p.S8R | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV55009848; called by muse, mutect2, varscan2
- PARP12 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV54934307; called by muse, mutect2, varscan2
- PARP14 | c.346A>T p.K116* | Nonsense Mutation (SNP) | VAF 30/148 reads (20%) | catalogued as COSV101518678; called by muse, mutect2, varscan2
- PATZ1 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs763469287, COSV56743865; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBXIP1 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 54/154 reads (35%) | catalogued as COSV63777220; called by muse, mutect2, varscan2
- PC | c.2009G>A p.G670D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1221556887, COSV58992763; called by muse, mutect2
- PCDH9 | c.254T>G p.I85S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60552279; called by muse, mutect2, varscan2
- PCDHA13 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.441); catalogued as COSV56503062; called by muse, mutect2, varscan2
- PCDHA2 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.499); catalogued as rs1554119311, COSV65367187; called by muse, mutect2, varscan2
- PCDHA8 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1353864944, COSV65336586; called by muse, mutect2, varscan2
- PCDHA9 | c.2270G>A p.R757K | Missense Mutation (SNP) | VAF 167/446 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs1554144887, COSV65326735; called by muse, mutect2, varscan2
- PCDHGA11 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as COSV53951842; called by muse, mutect2, varscan2
- PCDHGB1 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as rs867459693, COSV53940130; called by muse, mutect2
- PCDHGB2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.944); catalogued as rs535439542, COSV53898506; called by muse, mutect2, varscan2
- PCSK1 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1044737470, COSV60735394, COSV60737452; called by muse, mutect2, varscan2
- PCSK5 | c.5401A>C p.S1801R | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV101377226; called by muse, mutect2, varscan2
- PDCD7 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs774717943, COSV52600475; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 49/414 reads (12%) | catalogued as rs747131399; called by mutect2, varscan2
- PDSS1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 149/426 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV66059112; called by muse, mutect2, varscan2
- PDZD2 | c.1567G>T p.V523L | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56858703; called by muse, mutect2, varscan2
- PDZRN4 | c.1304T>G p.V435G (on ENST00000402685 / NM_001164595.2; = p.V177G on NM_013377.4) | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100115837, COSV54202110; called by muse, mutect2, varscan2
- PDZRN4 | c.1802A>G p.Q601R (on ENST00000402685 / NM_001164595.2; = p.Q343R on NM_013377.4) | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.196); catalogued as COSV54202123; called by muse, mutect2, varscan2
- PFAS | c.3959C>T p.S1320F | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1371108457, COSV58980444; called by muse, mutect2, varscan2
- PFKFB1 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 62/175 reads (35%) | PolyPhen benign (0.279); catalogued as rs771700798, COSV66628186; called by muse, mutect2, varscan2
- PGAM1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs371468578; called by muse, mutect2, varscan2
- PHACTR1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60667275; called by muse, mutect2, varscan2
- PHEX | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65075710; called by muse, mutect2, varscan2
- PHF2 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1171243513, COSV100822972; called by muse, mutect2, varscan2
- PHF3 | c.5513C>A p.P1838Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV50319580; called by muse, mutect2, varscan2
- PHLPP2 | c.3964G>T p.A1322S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.551); catalogued as COSV62424569; called by muse, mutect2, varscan2
- PHPT1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs764705291; called by muse, varscan2
- PIANP | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as COSV57707986; called by muse, mutect2, varscan2
- PIGN | c.2251_2252del p.L751Tfs*8 | Frame Shift Del (DEL) | VAF 36/150 reads (24%) | catalogued as rs1341720994; called by pindel, varscan2
- PIGR | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs529407537, COSV62903193; called by muse, mutect2, varscan2
- PIK3CG | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as rs752896730, COSV63248623; called by muse, mutect2, varscan2
- PIP4P2 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99575077; called by muse, mutect2
- PITX1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54762001; called by muse, varscan2
- PKD1L1 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV56965553; called by muse, mutect2, varscan2
- PKD1L1 | c.3482T>G p.L1161R | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56965561; called by muse, mutect2, varscan2
- PKHD1L1 | c.5338G>A p.A1780T | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.071); catalogued as COSV65743357; called by muse, mutect2, varscan2
- PKM | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58788537; called by muse, mutect2, varscan2
- PKM | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as rs149152236, COSV100064383; called by muse, mutect2, varscan2
- PLA2R1 | c.4119del p.G1374Afs*32 | Frame Shift Del (DEL) | VAF 38/128 reads (30%) | catalogued as rs746999253; called by mutect2, varscan2
- PLAG1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 99/176 reads (56%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV57611376; called by muse, mutect2, varscan2
- PLCB1 | c.2123C>T p.T708I | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as COSV62051577; called by muse, mutect2, varscan2
- PLCL2 | c.964G>A p.A322T (on ENST00000615277 / NM_001144382.2; = p.A196T on NM_015184.5) | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs906979876; called by muse, mutect2
- PLD1 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100578726, COSV60568208; called by muse, mutect2, varscan2
- PLEKHA6 | c.1634G>T p.R545M | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55333945; called by muse, mutect2, varscan2
- PLEKHH1 | c.3073C>T p.R1025W | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs749496824; called by muse, varscan2
- PLK1 | c.1078_1080del p.E360del | In Frame Del (DEL) | VAF 50/146 reads (34%) | catalogued as rs1230691153; called by pindel, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs772701630; called by mutect2, varscan2
- PLPPR4 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100926674, COSV100926676; called by muse, mutect2, varscan2
- PLXNC1 | c.2426del p.L809* | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | catalogued as rs1392040601; called by mutect2, pindel, varscan2
- PLXND1 | c.4454G>A p.R1485H | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388658515, COSV60713787; called by muse, mutect2, varscan2
- PNPLA3 | c.943A>C p.S315R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53378361; called by muse, mutect2, varscan2
- PNPLA6 | c.3522del p.S1175Pfs*10 (on ENST00000414982 / NM_001166111.2; = p.S1127Pfs*10 on NM_006702.5) | Frame Shift Del (DEL) | VAF 22/41 reads (54%) | catalogued as COSV55378573; called by mutect2, varscan2
- POFUT2 | c.1068G>T p.W356C | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV100499162, COSV57959070; called by muse, mutect2, varscan2
- POLR2A | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs777312684, COSV59492390; called by muse, mutect2, varscan2
- POM121L12 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs755460528, COSV68692870; called by muse, varscan2
- POMC | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775998713, COSV53034904; called by muse, mutect2, varscan2
- POMGNT1 | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 16/168 reads (10%) | PolyPhen probably damaging (1); catalogued as COSV64339922; called by muse, mutect2, varscan2
- POMGNT2 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs749833091, COSV60953499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POP1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs757141424, COSV62892845; called by muse, mutect2, varscan2
- POSTN | c.2036A>T p.E679V | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV65713011; called by muse, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs753902804; called by mutect2, varscan2
- PPP4R4 | c.1177T>G p.F393V | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV58554730; called by muse, mutect2, varscan2
- PPP4R4 | c.2425A>G p.K809E | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV58554740; called by muse, mutect2, varscan2
- PPP5C | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs866767367, COSV50140325; called by muse, mutect2
- PPP6R2 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV53293628; called by muse, mutect2, varscan2
- PRDM2 | c.196del p.R66Dfs*37 | Frame Shift Del (DEL) | VAF 138/699 reads (20%) | catalogued as rs112778466; called by mutect2, pindel, varscan2
- PRG4 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs772168924, COSV66624029; called by muse, mutect2, varscan2
- PRG4 | c.1975A>C p.T659P | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs760138464; called by muse, varscan2
- PRKCG | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs768380642, COSV54728018; called by muse, mutect2, varscan2
- PRKRA | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 60/200 reads (30%) | catalogued as COSV57868851; called by muse, mutect2, varscan2
- PRMT9 | c.2288C>T p.T763I | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs1293501023, COSV56853716; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 144/372 reads (39%) | catalogued as rs753236928; called by mutect2, varscan2
- PSME3IP1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58429239; called by muse, mutect2, varscan2
- PTCHD1 | c.2366del p.N789Mfs*8 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | catalogued as COSV65058929; called by mutect2, pindel, varscan2
- PTER | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as rs370657038; called by muse, mutect2, varscan2
- PTGR2 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50865801; called by muse, mutect2, varscan2
- PTPN14 | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 26/78 reads (33%) | catalogued as COSV65284195; called by muse, mutect2, varscan2
- PTPRD | c.4159G>A p.A1387T | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61934076; called by muse, mutect2
- PTPRK | c.4130+2T>C p.X1377_splice (on ENST00000368215 / NM_001291984.2; = p.X1378_splice on NM_002844.4) | Splice Site (SNP) | VAF 41/84 reads (49%) | catalogued as COSV100950291; called by muse, mutect2, varscan2
- PTPRM | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1278067890, COSV100154288; called by muse, mutect2
- PUS1 | c.401T>C p.M134T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs1260785513, COSV59035541; called by muse, mutect2, varscan2
- PUS3 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 109/657 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs1300700932, COSV99916727; called by muse, mutect2, varscan2
- PWP1 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 175/571 reads (31%) | catalogued as rs537077822, COSV69832983; called by muse, mutect2, varscan2
- PXDNL | c.3935C>T p.T1312M | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs780135369, COSV62478598; called by muse, mutect2, varscan2
- QRICH1 | c.845T>C p.L282S | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62615592; called by muse, mutect2, varscan2
- QRSL1 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 253/468 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV64687083; called by muse, mutect2, varscan2
- RAB41 | c.524C>T p.A175V (on ENST00000374473 / NM_001363807.1; = p.A174V on NM_001032726.3) | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52104018, COSV52105039; called by muse, mutect2, varscan2
- RABGAP1L | c.1103T>C p.M368T | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1427317164, COSV52296350; called by muse, mutect2, varscan2
- RAI2 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58964355; called by muse, mutect2, varscan2
- RALGAPA1 | c.1826del p.N609Ifs*2 | Frame Shift Del (DEL) | VAF 59/167 reads (35%) | catalogued as rs748033282; called by mutect2, varscan2
- RALGAPA2 | c.3855G>T p.E1285D | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99173087; called by muse, mutect2, varscan2
- RALGAPB | c.535G>C p.A179P | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99484606; called by muse, varscan2
- RAP1B | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 183/579 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV51668624; called by muse, mutect2, varscan2
- RAPGEF1 | c.2791G>T p.A931S | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.814); catalogued as COSV64699671, COSV64699813; called by muse, mutect2, varscan2
- RAPGEF1 | c.1752G>T p.K584N | Missense Mutation (SNP) | VAF 107/331 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV64699676; called by muse, mutect2, varscan2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 44/142 reads (31%) | catalogued as rs751690893; called by mutect2, varscan2
- RBMS3 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV56145466; called by muse, mutect2, varscan2
- RBPMS | c.183+1G>A p.X61_splice | Splice Site (SNP) | VAF 86/277 reads (31%) | catalogued as COSV99823555; called by muse, mutect2, varscan2
- RCOR3 | c.397del p.T133Lfs*7 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | catalogued as COSV65365594; called by pindel, varscan2
- REEP3 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 121/367 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs747010885, COSV53424789; called by muse, mutect2, varscan2
- RERE | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767855706, COSV100556747; called by muse, varscan2
- RESF1 | c.707T>C p.F236S | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57022249; called by muse, mutect2, varscan2
- RFC1 | c.2762T>C p.V921A (on ENST00000381897 / NM_001363496.2; = p.V920A on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV62899685; called by muse, mutect2, varscan2
- RFFL | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99265117; called by muse, mutect2
- RGL4 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51943892; called by muse, mutect2, varscan2
- RGS7 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV58542565, COSV58549685; called by muse, mutect2, varscan2
- RHBG | c.1247A>G p.K416R | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV54805248; called by muse, mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 108/390 reads (28%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RICTOR | c.2034del p.K678Nfs*14 | Frame Shift Del (DEL) | VAF 41/216 reads (19%) | catalogued as COSV57124299; called by mutect2, pindel, varscan2
- RIMBP2 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs371234096; called by muse, mutect2, varscan2
- RIMS1 | c.1761G>C p.W587C | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53456901; called by muse, mutect2, varscan2
- RIMS3 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV65504348; called by muse, mutect2, varscan2
- RIPOR1 | c.1652C>A p.T551N (on ENST00000379312 / NM_001193522.2; = p.T547N on NM_024519.4) | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV50225082; called by muse, mutect2, varscan2
- RNASE11 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV100250433; called by muse, mutect2
- RNF214 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs542552815, COSV56118238; called by muse, mutect2, varscan2
- RNF25 | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99828786; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 109/206 reads (53%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO1 | c.1864A>G p.K622E | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as COSV71394494; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL24 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 134/596 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV57245222; called by muse, varscan2
- RPP40 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60292101; called by muse, mutect2, varscan2
- RPUSD4 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV53599343; called by muse, mutect2, varscan2
- RSRC2 | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 64/379 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.916); catalogued as COSV59204617; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 49/418 reads (12%) | catalogued as rs747510098; called by mutect2, varscan2
- RYR2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV63686738; called by muse, mutect2, varscan2
- RYR2 | c.11516T>A p.L3839H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1156629658; called by muse, mutect2
- S100A2 | c.79A>C p.K27Q | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64184728; called by muse, mutect2, varscan2
- SAFB2 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1194729525; called by muse, mutect2
- SAP130 | c.2732A>G p.Y911C | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52097360; called by muse, mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 55/278 reads (20%) | catalogued as rs763290832; called by mutect2, varscan2
- SCN7A | c.1487A>G p.E496G | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV69271681; called by muse, mutect2, varscan2
- SCRN2 | c.437del p.G146Afs*50 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as rs750983392; called by mutect2, pindel, varscan2
- SDK1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs375595635; called by muse, mutect2, varscan2
- SEC24D | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54879989; called by muse, mutect2
- SEC24D | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1395265420, COSV54876555; called by muse, mutect2, varscan2
- SEL1L2 | c.1462T>G p.F488V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.34); catalogued as COSV53152499; called by muse, mutect2, varscan2
- SEMA4F | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs183645100, COSV60283379; called by muse, mutect2, varscan2
- SEMA7A | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.407); catalogued as rs183138976, COSV56090881; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 204/316 reads (65%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINB6 | c.1168G>A p.G390S (on ENST00000612421 / NM_001271823.2; = p.G371S on NM_004568.6) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762701058, COSV59565070; called by muse, mutect2, varscan2
- SERPINE2 | c.487+2T>G p.X163_splice | Splice Site (SNP) | VAF 33/90 reads (37%) | catalogued as COSV99296288; called by muse, mutect2, varscan2
- SETD1A | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs779640618, COSV52687905; called by muse, mutect2, varscan2
- SETD3 | c.1345A>G p.K449E | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs892597028, COSV59284542; called by muse, mutect2, varscan2
- SETDB1 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs749586165, COSV54983075, COSV99645512; called by muse, mutect2, varscan2
- SETX | c.6842+2T>C p.X2281_splice | Splice Site (SNP) | VAF 38/145 reads (26%) | catalogued as COSV99808604; called by muse, mutect2, varscan2
- SETX | c.4921G>A p.V1641I | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56385722; called by muse, mutect2, varscan2
- SEZ6L | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50664889, COSV50670140; called by muse, mutect2, varscan2
- SEZ6L2 | c.1924G>A p.D642N (on ENST00000308713 / NM_001114099.3; = p.D572N on NM_012410.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58099561; called by muse, varscan2
- SFSWAP | c.1610G>C p.G537A | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV55522202; called by muse, mutect2, varscan2
- SFTPA2 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 258/798 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1554851266, COSV100958696; called by mutect2, varscan2
- SGCG | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as COSV54560989; called by muse, mutect2, varscan2
- SGO1 | c.1564dup p.R522Kfs*29 (on ENST00000263753 / NM_001012410.5; = p.R253Kfs*29 on NM_138484.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 62/286 reads (22%) | catalogued as rs772386209; called by mutect2, varscan2
- SGSM1 | c.406T>A p.F136I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.146); catalogued as rs1309378732, COSV101240357; called by muse, mutect2, varscan2
- SH3D21 | c.1969dup p.T657Nfs*30 (on ENST00000453908 / NM_001162530.2; = p.T546Nfs*30 on NM_024676.5) | Frame Shift Ins (INS) | VAF 79/226 reads (35%) | catalogued as rs779458156; called by mutect2, varscan2
- SH3GL2 | c.56A>T p.E19V | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66047963; called by muse, mutect2, varscan2
- SHANK1 | c.2534C>A p.A845E | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs143486469, COSV53249762; called by muse, mutect2, varscan2
- SHANK2 | c.2978G>T p.G993V | Missense Mutation (SNP) | VAF 219/669 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99571749; called by muse, mutect2, varscan2
768 further variants in this file (450 protein-altering or splice-affecting, 294 silent, 24 other) are not listed here.
